Somatic mutation profile of tumor specimen HCM-WCMC-1344-C18-01A (aliquot HCM-WCMC-1344-C18-01A-05D-A937-36) from HCMI case HCM-WCMC-1344-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 46.6 years (17,024 days).
Specimen HCM-WCMC-1344-C18-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66006ce9-a0fe-47cf-ab97-c14a4e9a05cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1344-C18-12A (Saliva), aliquot HCM-WCMC-1344-C18-12A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4130db13-9a13-4795-a61f-2599fba23178

The open-access MAF lists 1,147 somatic variants for this specimen: 843 protein-altering or splice-affecting, 256 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 596, Silent 256, Frame Shift Del 168, Frame Shift Ins 44, Intron 25, Nonsense Mutation 23, 5'Flank 6, 3'UTR 6, Splice Region 5, 3'Flank 5, 5'UTR 4, Splice Site 3.

Variants (750 of 1,147; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 35/161 reads (22%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ACO2 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 81/358 reads (23%) | catalogued as rs387907389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 51/202 reads (25%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- C19orf12 | c.205G>A p.G69R (on ENST00000392278 / NM_001031726.3; = p.G58R on NM_031448.6) | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs515726205, CM118380, COSV100080664, COSV60364177; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 108/337 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 60/250 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCND3 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 67/409 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs786205867, CM124831; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 29/218 reads (13%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ1 | c.1343del p.P448Qfs*18 | Frame Shift Del (DEL) | VAF 63/340 reads (19%) | catalogued as rs397508087, CM097219; ClinVar: pathogenic; called by mutect2, varscan2
- LZTR1 | c.27dup p.Q10Afs*24 | Frame Shift Ins (INS) | VAF 44/164 reads (27%) | catalogued as rs587777613; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 40/232 reads (17%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 56/220 reads (25%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AARS1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs765846298, COSV55747318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA2 | c.1671del p.E558Rfs*3 (on ENST00000614293; = p.E528Rfs*3 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/158 reads (19%) | catalogued as COSV55803541; called by mutect2, varscan2
- ABHD12 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1239867385; called by muse, mutect2
- ABHD18 | c.699G>A p.T233= (on ENST00000398965 / NM_001039717.2; = p.T106= on NM_025097.2 and 10 other RefSeq transcripts) | Splice Region (SNP) | VAF 41/162 reads (25%) | catalogued as rs201083117; called by muse, mutect2, varscan2
- ABHD2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs757210313, COSV100756383, COSV61775010; called by muse, mutect2
- ACAD8 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1278727402; called by muse, mutect2, varscan2
- ACP6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 37/162 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782324354; called by muse, mutect2, varscan2
- ACSL6 | c.592G>A p.V198M (on ENST00000379240; = p.V223M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368653510; called by muse, mutect2, varscan2
- ACVR2A | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296122552, COSV54021353; called by muse, mutect2
- ADAM10 | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV53052302; called by muse, mutect2, varscan2
- ADAM8 | c.1281dup p.E428Rfs*17 | Frame Shift Ins (INS) | VAF 45/214 reads (21%) | catalogued as rs753471255; called by mutect2, varscan2
- ADAMTS14 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 49/400 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs145276866; called by muse, mutect2, varscan2
- ADCY3 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1333561857, COSV53164277; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 30/246 reads (12%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs538552021, COSV66925660; called by muse, mutect2, varscan2
- ADGRB1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs1201951121; called by muse, mutect2, varscan2
- ADGRV1 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.312); catalogued as COSV67992605; called by muse, mutect2, varscan2
- ADGRV1 | c.11674C>T p.R3892W | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as rs766913299, COSV67979727; called by muse, mutect2
- ADH1A | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs760558326; called by muse, mutect2, varscan2
- ADNP2 | c.2797G>A p.V933I | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs368537313; called by muse, mutect2, varscan2
- ADRA2A | c.833del p.G278Afs*64 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | catalogued as rs1564745697; called by mutect2, varscan2
- ADRA2C | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs1213435958; called by muse, mutect2, varscan2
- AGBL5 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747996062, COSV59938069; called by muse, mutect2, varscan2
- ALDH2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 73/360 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1453018126, COSV55666998; called by muse, varscan2
- ALDH5A1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 88/377 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs755160772; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH7A1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs746212816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH4 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs777313140; called by muse, mutect2, varscan2
- AMBRA1 | c.3787G>A p.A1263T (on ENST00000458649 / NM_001367468.1; = p.A1173T on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/354 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs964199125, COSV100095536; called by muse, mutect2, varscan2
- ANKRD10 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57444860; called by muse, mutect2, varscan2
- ANKRD13B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs752789986; called by muse, mutect2, varscan2
- ANKRD36C | c.4764dup p.Q1589Tfs*11 | Frame Shift Ins (INS) | VAF 39/294 reads (13%) | catalogued as rs200875477; called by mutect2, varscan2
- ANXA10 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV63738514; called by muse, mutect2
- ANXA11 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs760637842; called by muse, mutect2, varscan2
- AOC1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760642299; called by muse, mutect2, varscan2
- AP5Z1 | c.2086dup p.Q696Pfs*67 | Frame Shift Ins (INS) | VAF 32/236 reads (14%) | catalogued as rs771683676; called by mutect2, varscan2
- ARAP1 | c.932C>T p.A311V (on ENST00000393609 / NM_001040118.2; = p.A66V on NM_015242.4) | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs201444185, CM142293, COSV61993696; called by muse, mutect2, varscan2
- ARHGEF10L | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs750552676, COSV51440978; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 66/314 reads (21%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARID3B | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs145901163; called by muse, mutect2, varscan2
- ARL5B | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66011055; called by muse, mutect2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 59/298 reads (20%) | catalogued as rs965020534; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 49/288 reads (17%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ATP10A | c.2903G>A p.R968H | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs150976669; called by muse, mutect2
- ATP8A1 | c.3029C>T p.A1010V | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs1055141971, COSV52533843; called by muse, mutect2
- ATRX | c.4577C>T p.A1526V | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV64881393; called by muse, mutect2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 40/220 reads (18%) | catalogued as rs1288664341; called by mutect2, varscan2
- B3GAT2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 59/309 reads (19%) | catalogued as rs750513549, COSV100017508, COSV57769997, COSV57775208; called by muse, mutect2, varscan2
- B4GALT7 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567512466; called by muse, mutect2, varscan2
- BAHCC1 | c.7004C>G p.A2335G | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV57031339; called by muse, mutect2, varscan2
- BNC1 | c.2717A>G p.Y906C | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.747); catalogued as COSV61756846; called by muse, mutect2, varscan2
- BTD | c.862A>G p.M288V | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs757604137; called by muse, mutect2, varscan2
- C15orf39 | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs201514875, COSV100641353, COSV62297986; called by muse, mutect2, varscan2
- C16orf96 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs950903112; called by muse, mutect2, varscan2
- C2CD3 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 38/261 reads (15%) | catalogued as rs1406007301, CD164515; called by mutect2, varscan2
- CACNA1S | c.1149A>C p.E383D | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs544185379; called by muse, mutect2, varscan2
- CAND2 | c.1768C>T p.R590W (on ENST00000456430 / NM_001162499.2; = p.R497W on NM_012298.3) | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1392836335, COSV55992521; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | catalogued as rs762770988, COSV62756627; called by mutect2, varscan2
- CARS2 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs759804272, COSV57285563; called by muse, mutect2, varscan2
- CASD1 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 59/406 reads (15%) | catalogued as rs1228214882, COSV51972279; called by muse, mutect2, varscan2
- CATSPERG | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs547897343; called by muse, mutect2, varscan2
- CCDC124 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759811844; called by muse, mutect2, varscan2
- CCDC141 | c.2906C>A p.S969Y | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV99835970; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 42/176 reads (24%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC9 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs769602417; called by muse, mutect2, varscan2
- CDH12 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV66410447, COSV66438733; called by muse, mutect2
- CDH23 | c.5455C>A p.L1819M | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV99822080; called by muse, mutect2, varscan2
- CDH24 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746379911, COSV57458875; called by muse, mutect2, varscan2
- CDR2L | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1259917122, COSV104398160; called by muse, mutect2, varscan2
- CDYL | c.298G>A p.V100M (on ENST00000328908 / NM_001368125.1; = p.V46M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/469 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs145622412; called by muse, mutect2, varscan2
- CECR2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs368613674, COSV52849609, COSV99379044; called by muse, varscan2
- CELF6 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs202213817; called by muse, mutect2, varscan2
- CELSR2 | c.3035G>A p.R1012H | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as rs1037932407; called by muse, mutect2, varscan2
- CELSR2 | c.8767C>T p.H2923Y | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1291388409, COSV54772597; called by muse, mutect2, varscan2
- CEP170B | c.3499C>T p.R1167C (on ENST00000453495; = p.R1096C on NM_015005.3) | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866933875, COSV69024975; called by muse, mutect2, varscan2
- CEP295 | c.660del p.K220Nfs*29 | Frame Shift Del (DEL) | VAF 36/290 reads (12%) | catalogued as COSV57359099; called by mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 56/234 reads (24%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP54 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs981647152; called by muse, mutect2
- CHD4 | c.1895G>A p.R632Q (on ENST00000357008 / NM_001363606.2; = p.R645Q on NM_001273.5) | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1356961959; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 47/238 reads (20%) | catalogued as rs1322050057; called by mutect2, varscan2
- CHD9 | c.7291del p.R2431Gfs*8 (on ENST00000398510 / NM_001382353.1; = p.R2415Gfs*8 on NM_025134.7) | Frame Shift Del (DEL) | VAF 38/298 reads (13%) | catalogued as rs748826986; called by mutect2, varscan2
- CHPT1 | c.485del p.F162Sfs*23 | Frame Shift Del (DEL) | VAF 46/385 reads (12%) | catalogued as rs755424899; called by mutect2, varscan2
- CHRM1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756528929, COSV61006252; called by muse, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 74/368 reads (20%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 33/408 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV58886727; called by muse, mutect2
- CLPX | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as rs1163453717; called by muse, mutect2
- CMTM2 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1418049635; called by muse, mutect2, varscan2
- CNOT3 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 99/477 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs372481652; called by muse, mutect2, varscan2
- CNTN5 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV54321735; called by muse, mutect2, varscan2
- COBL | c.3282del p.K1094Nfs*20 | Frame Shift Del (DEL) | VAF 58/404 reads (14%) | catalogued as rs1562810271; called by mutect2, varscan2
- COL11A1 | c.1735del p.R579Gfs*54 | Frame Shift Del (DEL) | VAF 38/253 reads (15%) | catalogued as COSV62195334; called by mutect2, varscan2
- CRTC1 | c.1713dup p.S572Qfs*4 | Frame Shift Ins (INS) | VAF 30/156 reads (19%) | catalogued as rs769538822; called by mutect2, varscan2
- CSMD1 | c.5299G>A p.E1767K (on ENST00000520002; = p.E1766K on NM_033225.6) | Missense Mutation (SNP) | VAF 84/413 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1305727463, COSV59345424; called by muse, mutect2, varscan2
- CSMD2 | c.6538+1G>C p.X2180_splice | Splice Site (SNP) | VAF 32/186 reads (17%) | catalogued as COSV53912091; called by muse, mutect2, varscan2
- CUEDC2 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs753914938; called by muse, mutect2, varscan2
- CUL3 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs759758641, COSV52362153; called by muse, varscan2
- CUX2 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1239347097; called by muse, mutect2, varscan2
- DAO | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566264618, COSV57323592; called by muse, mutect2, varscan2
- DAP | c.215del p.P72Rfs*148 | Frame Shift Del (DEL) | VAF 44/228 reads (19%) | catalogued as rs777516488; called by mutect2, varscan2
- DBH | c.1781del p.P594Hfs*87 | Frame Shift Del (DEL) | VAF 54/238 reads (23%) | catalogued as COSV67549641; called by mutect2, varscan2
- DCAF11 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs750376750; called by muse, mutect2
- DEPDC7 | c.181C>T p.R61* (on ENST00000241051 / NM_001077242.2; = p.R52* on NM_139160.2) | Nonsense Mutation (SNP) | VAF 36/278 reads (13%) | catalogued as rs1326267387; called by muse, mutect2, varscan2
- DGCR8 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 55/358 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs778992846; called by muse, mutect2, varscan2
- DHX33 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753632223, COSV56579753; called by muse, mutect2, varscan2
- DIDO1 | c.6659G>A p.S2220N | Missense Mutation (SNP) | VAF 68/337 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1469304233; called by muse, mutect2, varscan2
- DLGAP1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 88/381 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as rs142650515; called by muse, mutect2, varscan2
- DMXL2 | c.8756del p.G2919Vfs*48 | Frame Shift Del (DEL) | VAF 49/285 reads (17%) | catalogued as COSV51847581; called by mutect2, varscan2
- DNAH2 | c.7024C>T p.R2342* | Nonsense Mutation (SNP) | VAF 53/260 reads (20%) | catalogued as rs749486150, COSV101209042; called by muse, mutect2, varscan2
- DNHD1 | c.11059C>T p.P3687S | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs866863010; called by muse, mutect2, varscan2
- DNMT3L | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1265705625; called by muse, mutect2, varscan2
- DOCK1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.184); catalogued as rs776990526; called by muse, varscan2
- DOK2 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 23/431 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52387861; called by muse, mutect2
- DPF2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs994854120, COSV52890510; called by muse, mutect2, varscan2
- DRD5 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576727; called by muse, mutect2, varscan2
- DRD5 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as rs143535200; called by muse, mutect2, varscan2
- DSCAML1 | c.5347C>T p.R1783W (on ENST00000321322; = p.R1723W on NM_020693.4) | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454536192, COSV100356033; called by muse, mutect2, varscan2
- DUSP16 | c.1633G>C p.A545P | Missense Mutation (SNP) | VAF 72/357 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99963406; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 56/244 reads (23%) | catalogued as rs772082432; called by mutect2, varscan2
- EIF2B1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1245638011, COSV53015723; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 36/160 reads (23%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF4ENIF1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 84/410 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314697052; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 63/306 reads (21%) | catalogued as rs766700925; called by mutect2, varscan2
- ENTPD6 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs184517540, COSV61750909; called by muse, mutect2, varscan2
- EP400 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs764793090, COSV100201239; called by muse, mutect2, varscan2
- EPG5 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 69/386 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as rs201678945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPX | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342884566; called by muse, mutect2, varscan2
- ERCC6 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs776462885, COSV63388218; called by muse, mutect2, varscan2
- FAM133A | c.538dup p.R180Kfs*7 | Frame Shift Ins (INS) | VAF 32/176 reads (18%) | catalogued as rs1273788336; called by mutect2, varscan2
- FASTKD2 | c.74del p.F25Sfs*10 | Frame Shift Del (DEL) | VAF 40/250 reads (16%) | catalogued as COSV52697899; called by mutect2, varscan2
- FAT3 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs780430076; called by muse, mutect2, varscan2
- FBLL1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100606194, COSV57924540; called by muse, mutect2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | catalogued as rs748969702; called by mutect2, varscan2
- FGFR4 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.7); catalogued as rs754036845, COSV52811197; called by muse, mutect2
- FNDC5 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs904804099; called by muse, mutect2
- FOXF1 | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs747243553; called by muse, mutect2, varscan2
- FOXN3 | c.287dup p.S97Ifs*6 | Frame Shift Ins (INS) | VAF 52/296 reads (18%) | catalogued as rs760347049; called by mutect2, varscan2
- FRRS1 | c.1681T>C p.C561R | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs745491322; called by muse, mutect2, varscan2
- GALNT18 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57158369; called by muse, varscan2
- GALNT9 | c.1804C>T p.R602W (on ENST00000328957 / NM_001122636.2; = p.R236W on NM_021808.3) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs747853052, COSV61100626, COSV61102717; called by muse, mutect2, varscan2
- GET3 | c.982dup p.A328Gfs*90 | Frame Shift Ins (INS) | VAF 44/210 reads (21%) | catalogued as rs763284415; called by mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 49/222 reads (22%) | catalogued as rs771881138; called by mutect2, varscan2
- GJA8 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 70/355 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs372038463; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 44/192 reads (23%) | catalogued as rs749150409; called by mutect2, varscan2
- GML | c.421del p.V141Yfs*6 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | catalogued as COSV55277551; called by mutect2, varscan2
- GNAS | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs758002061; called by muse, mutect2, varscan2
- GOLGA4 | c.4098del p.V1367Lfs*10 | Frame Shift Del (DEL) | VAF 33/282 reads (12%) | catalogued as rs768760517; called by mutect2, varscan2
- GP6 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs1274065849; called by muse, mutect2
- GPD1L | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 46/479 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1482453934; called by muse, mutect2
- GPLD1 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs772564077; called by muse, mutect2, varscan2
- GPR160 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs573747285, COSV63472804; called by muse, mutect2, varscan2
- GPR75 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.681); catalogued as COSV61826170; called by muse, mutect2
- GPT | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1379453991; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 42/216 reads (19%) | catalogued as rs750293240, COSV55140417; called by mutect2, varscan2
- HAGHL | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1222356019; called by muse, mutect2, varscan2
- HDAC1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs1265388078, COSV61482059; called by muse, mutect2, varscan2
- HDAC11 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 62/271 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as rs142419489; called by muse, mutect2, varscan2
- HDX | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1316677076; called by muse, mutect2, varscan2
- HEATR5A | c.5426G>A p.R1809Q | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs559824863, COSV101119455; called by muse, mutect2, varscan2
- HEATR5B | c.3931C>T p.R1311* | Nonsense Mutation (SNP) | VAF 48/345 reads (14%) | catalogued as rs1348209192; called by muse, mutect2, varscan2
- HECTD4 | c.9718del p.A3240Rfs*26 | Frame Shift Del (DEL) | VAF 28/213 reads (13%) | catalogued as rs754540615; called by mutect2, varscan2
- HECW2 | c.4477C>T p.R1493* | Nonsense Mutation (SNP) | VAF 40/318 reads (13%) | catalogued as COSV99646863; called by muse, mutect2, varscan2
- HERC1 | c.10714C>A p.R3572S | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.131); catalogued as COSV101496883; called by muse, mutect2, varscan2
- HIVEP3 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs762301632, COSV56010507; called by muse, mutect2, varscan2
- HLA-DQB2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.114); catalogued as COSV68614867; called by muse, mutect2, varscan2
- HSD17B1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs778944174; called by muse, mutect2, varscan2
- HSPG2 | c.8212G>A p.V2738M | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144862631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUS1B | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs757961681, COSV100033535; called by muse, mutect2, varscan2
- ICE2 | c.1899dup p.P634Tfs*7 | Frame Shift Ins (INS) | VAF 40/250 reads (16%) | catalogued as rs773511663; called by mutect2, varscan2
- IGHA2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782085693; called by muse, mutect2, varscan2
- IGSF9B | c.1559T>C p.V520A | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV58064601; called by muse, mutect2, varscan2
- INPP5K | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV57440835; called by muse, mutect2
- INTS1 | c.3431C>T p.S1144L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs375215357; called by muse, mutect2, varscan2
- INTS3 | c.2588G>A p.R863Q | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1292651271; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 48/268 reads (18%) | catalogued as rs761880048; called by mutect2, varscan2
- KANK2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 42/287 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs370098562; called by muse, mutect2, varscan2
- KCNAB3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.323); catalogued as COSV58050819; called by muse, varscan2
- KCND2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576645; called by muse, mutect2, varscan2
- KCNG1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs761694072, COSV65367996; called by muse, mutect2, varscan2
- KCNG2 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161088582; called by muse, varscan2
- KIAA1109 | c.7613C>T p.A2538V | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.265); catalogued as rs368105993; called by muse, mutect2, varscan2
- KIAA1522 | c.947G>A p.R316H (on ENST00000373480 / NM_001198972.2; = p.R375H on NM_020888.3) | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1353411253, COSV53866155; called by muse, mutect2, varscan2
- KIF20B | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755790468, COSV53310332; called by muse, mutect2, varscan2
- KIFC1 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 91/485 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746419470; called by muse, mutect2, varscan2
- KLF16 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464155965, COSV51736425; called by muse, mutect2, varscan2
- KLHDC4 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV54508110; called by muse, mutect2, varscan2
- KLHL30 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.051); catalogued as rs778622350; called by muse, mutect2, varscan2
- KMT2B | c.3057del p.G1020Afs*4 | Frame Shift Del (DEL) | VAF 33/263 reads (13%) | catalogued as rs868041281; called by mutect2, varscan2
- KPRP | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1463856931, COSV64222717; called by muse, mutect2, varscan2
- KRTAP16-1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.887); catalogued as rs777158668, COSV66939329; called by muse, mutect2
- KRTAP4-3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs1442367115, COSV101194142; called by muse, varscan2
- KSR2 | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs376679729, COSV56667955; called by muse, mutect2, varscan2
- LAD1 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs140432313; called by muse, mutect2, varscan2
- LAMA5 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756189022, COSV53361493; called by muse, mutect2, varscan2
- LAMB2 | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs376290063; called by muse, varscan2
- LAMB4 | c.2933T>C p.V978A | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1229054389, COSV52730013; called by muse, mutect2, varscan2
- LGI4 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 57/297 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV59535444; called by muse, mutect2, varscan2
- LIMA1 | c.1605dup p.T536Hfs*2 | Frame Shift Ins (INS) | VAF 52/246 reads (21%) | catalogued as rs1400710960; called by mutect2, varscan2
- LONRF2 | c.1531C>T p.R511* | Nonsense Mutation (SNP) | VAF 59/307 reads (19%) | catalogued as rs771704410, COSV66540256; called by muse, mutect2, varscan2
- LRGUK | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs750348362, COSV53634666; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 83/350 reads (24%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC27 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 64/361 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs769773519, COSV59812433; called by muse, mutect2, varscan2
- LRRC4B | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs1362877053; called by muse, mutect2
- LRRC57 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 41/235 reads (17%) | catalogued as COSV52999431; called by muse, mutect2, varscan2
- LRRC70 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs146092308; called by muse, mutect2, varscan2
- LRRC74B | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs747155313, COSV61187723; called by muse, mutect2, varscan2
- LRRK1 | c.4231G>A p.G1411R | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211781027, COSV52624132; called by muse, mutect2, varscan2
- LRRTM3 | c.1550T>C p.M517T | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as rs1179521268; called by muse, mutect2
- MACF1 | c.8771T>A p.I2924N | Missense Mutation (SNP) | VAF 32/195 reads (16%) | catalogued as COSV57105138, COSV57124948; called by muse, mutect2, varscan2
- MACIR | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.062); catalogued as rs1554237601; called by muse, varscan2
- MACROH2A2 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs779007856; called by muse, mutect2, varscan2
- MAGEL2 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.731); catalogued as rs370022000, COSV100045952; called by muse, mutect2, varscan2
- MAN2B2 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs769800406; called by muse, mutect2, varscan2
- MAP2K3 | c.295G>A p.V99M (on ENST00000342679 / NM_145109.3; = p.V70M on NM_002756.4) | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1156837659; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 42/295 reads (14%) | catalogued as rs765962881; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 50/328 reads (15%) | catalogued as rs777328830; called by mutect2, varscan2
- MARF1 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs369224578; called by muse, mutect2, varscan2
- MATN4 | c.1450C>T p.R484W (on ENST00000372754; = p.R443W on NM_003833.4) | Missense Mutation (SNP) | VAF 66/319 reads (21%) | PolyPhen probably damaging (1); catalogued as rs202220426; called by muse, mutect2, varscan2
- MDN1 | c.15772C>T p.R5258* | Nonsense Mutation (SNP) | VAF 53/399 reads (13%) | catalogued as rs1311244151; called by muse, mutect2, varscan2
- MEGF6 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1019813107; called by muse, varscan2
- MEI4 | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs539939524; called by muse, mutect2, varscan2
- METTL2B | c.1079T>C p.M360T | Missense Mutation (SNP) | VAF 73/464 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773126594; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 75/252 reads (30%) | catalogued as rs762448666; called by mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 64/318 reads (20%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MOAP1 | c.37A>G p.M13V | Missense Mutation (SNP) | VAF 78/388 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as rs767631342, COSV52092503; called by muse, varscan2
- MOB3C | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV54718645; called by muse, mutect2, varscan2
- MRGPRX1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 57/483 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as rs750486969, COSV57105964; called by muse, mutect2, varscan2
- MRM3 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 52/405 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.251); catalogued as rs770057184, COSV58679851; called by muse, mutect2, varscan2
- MRPS5 | c.336del p.G113Efs*14 | Frame Shift Del (DEL) | VAF 28/256 reads (11%) | catalogued as rs1558684714; called by mutect2, varscan2
- MSN | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1465848452, COSV64303704; called by muse, mutect2
- MST1R | c.3544G>A p.V1182M | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs771218531; called by muse, mutect2, varscan2
- MTMR12 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.67); catalogued as rs1259407263; called by muse, mutect2, varscan2
- MUC16 | c.12058G>A p.V4020I | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as rs373276168; called by muse, mutect2, varscan2
- MUC16 | c.4682C>T p.T1561M | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs199772369; called by muse, mutect2, varscan2
- MUC4 | c.15613C>T p.R5205W (on ENST00000463781 / NM_018406.7; = p.R969W on NM_004532.6) | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs780841763; called by muse, mutect2, varscan2
- MYBBP1A | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145628809; called by muse, mutect2, varscan2
- MYC | c.1316C>T p.A439V (on ENST00000377970; = p.A454V on NM_002467.6) | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV52372769; called by muse, mutect2, varscan2
- MYH7 | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV62518092; called by muse, mutect2, varscan2
- NAGA | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs367803688; called by muse, mutect2, varscan2
- NAV2 | c.3283G>A p.A1095T (on ENST00000396087 / NM_001244963.2; = p.A1072T on NM_145117.5) | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs751815417, COSV60656569; called by muse, mutect2, varscan2
- NAV3 | c.6848G>A p.R2283H (on ENST00000397909 / NM_001024383.2; = p.R2261H on NM_014903.6) | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758160570; called by muse, mutect2, varscan2
- NBPF12 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1343726720; called by muse, mutect2, varscan2
- NCKAP5L | c.3926G>C p.G1309A | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV60129176; called by muse, mutect2, varscan2
- NELFB | c.1351T>C p.Y451H | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.712); catalogued as COSV58026226; called by muse, mutect2, varscan2
- NEO1 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as rs952837071; called by muse, mutect2
- NEURL3 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 36/449 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1318864484; called by muse, mutect2
- NFATC4 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs1054880467; called by muse, mutect2
- NFKBIB | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs746214449; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 26/208 reads (13%) | catalogued as rs145147241; called by mutect2, varscan2
- NKPD1 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100521561; called by muse, mutect2, varscan2
- NOX3 | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV50156274; called by muse, mutect2, varscan2
- NPAS4 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1430096101, COSV60652325; called by muse, mutect2, varscan2
- NPC1L1 | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as rs778913010, COSV99206087; called by muse, mutect2, varscan2
- NPW | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.068); catalogued as rs1371540489; called by muse, varscan2
- NR1H2 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1175038242; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 51/282 reads (18%) | catalogued as rs776154715; called by mutect2, varscan2
- NRK | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as rs760958200; called by muse, mutect2, varscan2
- NUP205 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs997385891, COSV53658239, COSV53659887; called by muse, mutect2, varscan2
- OCRL | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 32/156 reads (21%) | catalogued as CM055470; called by muse, mutect2, varscan2
- OPLAH | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 101/344 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs575947480, COSV101470788; called by muse, mutect2, varscan2
- OPTC | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs150633473, COSV65867446; called by muse, mutect2, varscan2
- OR2B6 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376301628; called by muse, mutect2, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 62/270 reads (23%) | catalogued as COSV57137289; called by mutect2, varscan2
- OR51D1 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1360024456; called by muse, mutect2, varscan2
- OR51S1 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV59057989; called by muse, mutect2, varscan2
- OR5C1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 85/337 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs374146289, COSV65456046; called by muse, mutect2, varscan2
- OR6B1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200541258; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 35/166 reads (21%) | catalogued as rs746200712; called by mutect2, varscan2
- OR8J3 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56879310; called by muse, mutect2, varscan2
- P2RX3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs201667208; called by muse, mutect2, varscan2
- PALMD | c.1036dup p.R346Kfs*35 | Frame Shift Ins (INS) | VAF 52/330 reads (16%) | catalogued as rs1404233567; called by mutect2, varscan2
- PCDH11Y | c.2569G>A p.V857I (on ENST00000400457 / NM_032973.2; = p.V846I on NM_032971.3) | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs777010130, COSV53075849; called by muse, mutect2, varscan2
- PCDHB3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 93/538 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV50564677, COSV50581609; called by muse, mutect2, varscan2
- PCDHGA8 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 80/369 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.052); catalogued as rs762034418; called by muse, mutect2, varscan2
- PCDHGB1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99536286; called by muse, mutect2, varscan2
- PCSK4 | c.1874dup p.R626Afs*71 | Frame Shift Ins (INS) | VAF 36/234 reads (15%) | catalogued as rs1174914612; called by mutect2, varscan2
- PDE4D | c.487C>T p.R163W (on ENST00000340635 / NM_001104631.2; = p.R27W on NM_006203.4) | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs749395945, COSV58969110; called by muse, mutect2, varscan2
- PDE8A | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as rs769259809, COSV59637818; called by muse, mutect2
- PDGFRL | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs537107335, COSV52410896; called by muse, mutect2, varscan2
- PDPK1 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs779064858, COSV51912155; called by muse, mutect2, varscan2
- PERM1 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV58023799; called by muse, mutect2, varscan2
- PHF3 | c.6028C>T p.R2010* | Nonsense Mutation (SNP) | VAF 57/375 reads (15%) | catalogued as rs746217827; called by muse, mutect2, varscan2
- PHRF1 | c.2515G>A p.D839N (on ENST00000264555 / NM_001286581.2; = p.D838N on NM_020901.4) | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1404363789; called by muse, mutect2, varscan2
- PIGV | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 57/298 reads (19%) | catalogued as rs770220740, CM145505; called by muse, mutect2, varscan2
- PKD1 | c.9068T>C p.M3023T | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.199); catalogued as rs377227184; called by muse, mutect2, varscan2
- PLEC | c.8087A>G p.Q2696R (on ENST00000322810 / NM_201380.4; = p.Q2586R on NM_000445.5) | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1438756624; called by muse, mutect2
- PLXNA1 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs749976520; called by muse, mutect2, varscan2
- POLR1A | c.4159C>T p.R1387W | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs570647558; called by muse, mutect2, varscan2
- POLR2A | c.21del p.S8Rfs*19 | Frame Shift Del (DEL) | VAF 41/220 reads (19%) | catalogued as rs762376289; called by mutect2, varscan2
- POLR2H | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV56178018; called by muse, mutect2
- PPME1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV100076284; called by muse, mutect2
- PRDM16 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs377688111; called by muse, mutect2, varscan2
- PRKAR1A | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1472324247; ClinVar: uncertain significance; called by muse, mutect2
- PRKDC | c.4954del p.I1652Ffs*37 | Frame Shift Del (DEL) | VAF 32/240 reads (13%) | catalogued as COSV104404398; called by mutect2, varscan2
- PRR23A | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV67213803; called by muse, mutect2, varscan2
- PSG3 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1384469320, COSV100549214; called by muse, mutect2, varscan2
- PTPN23 | c.4285C>T p.R1429W | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200695676, COSV55546114; called by muse, mutect2, varscan2
- PTPN7 | c.434A>C p.E145A (on ENST00000495688; = p.E184A on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.093); catalogued as COSV58312604; called by muse, mutect2, varscan2
- PXDN | c.2240C>T p.T747I | Missense Mutation (SNP) | VAF 89/368 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53245778; called by muse, mutect2, varscan2
- PXDN | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1558496208, COSV99414516; called by muse, mutect2, varscan2
- PXK | c.1375del p.R459Efs*4 | Frame Shift Del (DEL) | VAF 52/255 reads (20%) | catalogued as rs751548577; called by mutect2, varscan2
- RAB11FIP1 | c.3387dup p.A1130Sfs*9 | Frame Shift Ins (INS) | VAF 42/308 reads (14%) | catalogued as rs752866106; called by mutect2, varscan2
- RABL6 | c.1144del p.E382Rfs*217 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | catalogued as COSV61033434; called by mutect2, varscan2
- RAP1GAP2 | c.1124T>C p.M375T | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1260592197, COSV54585190; called by muse, mutect2, varscan2
- RICTOR | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as rs759467094; called by muse, mutect2, varscan2
- RNASEL | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs35553278; called by muse, mutect2, varscan2
- RNF213 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs531491005; called by muse, mutect2, varscan2
- RNF43 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs747371137, COSV68458423; called by muse, mutect2, varscan2
- RNF44 | c.577del p.Q193Sfs*80 | Frame Shift Del (DEL) | VAF 40/180 reads (22%) | catalogued as rs748776013; called by mutect2, varscan2
- ROBO4 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.369); catalogued as COSV100127173, COSV60627644; called by muse, mutect2
- ROCK2 | c.412del p.W138Gfs*31 | Frame Shift Del (DEL) | VAF 52/294 reads (18%) | catalogued as rs755738345; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 38/248 reads (15%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RUNDC3B | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55949445, COSV55961291; called by muse, mutect2, varscan2
- SALL3 | c.3440G>A p.G1147D | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs747460032; called by muse, mutect2, varscan2
- SART3 | c.2618C>T p.S873L (on ENST00000228284; = p.S855L on NM_014706.4) | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs146354825; called by muse, mutect2, varscan2
- SCN1A | c.5510C>T p.P1837L (on ENST00000303395 / NM_001202435.3; = p.P1826L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs149225252, COSV57669951; ClinVar: uncertain significance; called by muse, varscan2
- SCN3A | c.4961C>T p.A1654V | Missense Mutation (SNP) | VAF 92/537 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51801173; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 26/182 reads (14%) | catalogued as rs763181092; called by mutect2, varscan2
- SEC16A | c.5065G>A p.A1689T | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs773116220; called by muse, mutect2, varscan2
- SEC23A | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs749527149; called by muse, mutect2, varscan2
- SEC62 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | catalogued as COSV61260942; called by muse, mutect2, varscan2
- SELENOM | c.140dup p.Sec48Mfs*34 | Frame Shift Ins (INS) | VAF 56/283 reads (20%) | catalogued as rs753938731; called by mutect2, varscan2
- SEMA4D | c.1963G>C p.A655P | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs986840497; called by muse, mutect2, varscan2
- SERPINA11 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 43/459 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs199659692; called by muse, mutect2
- SETX | c.7246A>G p.K2416E | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56380275; called by muse, mutect2
- SH2D7 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs74466400; called by muse, mutect2, varscan2
- SH3BGRL2 | c.249del p.F83Lfs*13 | Frame Shift Del (DEL) | VAF 50/251 reads (20%) | catalogued as COSV63965661; called by mutect2, varscan2
- SIGLEC9 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750378417; called by muse, mutect2, varscan2
- SKIV2L | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.761); catalogued as rs774644201, COSV61713745; called by muse, mutect2, varscan2
- SKOR1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58244651; called by muse, mutect2, varscan2
- SLC15A1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs199996553; called by muse, mutect2
- SLC25A22 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs1332876414; called by muse, mutect2, varscan2
- SLC4A5 | c.2605G>A p.G869S | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs770652020, COSV61035171; called by muse, mutect2
- SLC7A10 | c.471del p.T158Pfs*12 | Frame Shift Del (DEL) | VAF 41/270 reads (15%) | catalogued as rs753589038, COSV53507811; called by mutect2, varscan2
- SLC8A1 | c.1368T>A p.D456E | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247555; called by muse, mutect2
- SLF2 | c.2360del p.L787* | Frame Shift Del (DEL) | VAF 38/226 reads (17%) | catalogued as rs1007972651, COSV53275602; called by mutect2, varscan2
- SNAPC2 | c.799del p.Q267Sfs*38 | Frame Shift Del (DEL) | VAF 60/309 reads (19%) | catalogued as rs769564442; called by mutect2, varscan2
- SORCS1 | c.214del p.L72Sfs*2 | Frame Shift Del (DEL) | VAF 55/331 reads (17%) | catalogued as COSV99545196; called by mutect2, varscan2
- SOX11 | c.1148del p.G383Afs*39 | Frame Shift Del (DEL) | VAF 54/283 reads (19%) | catalogued as rs1553328038; called by mutect2, varscan2
- SOX12 | c.381del p.G128Vfs*171 | Frame Shift Del (DEL) | VAF 46/226 reads (20%) | catalogued as rs1345087091; called by mutect2, varscan2
- SOX17 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1381547285; called by muse, mutect2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 50/236 reads (21%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPI1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs1370001180; called by muse, mutect2, varscan2
- SPTBN4 | c.6893G>A p.R2298Q | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as rs907020848, COSV100150157; called by muse, mutect2
- SRCIN1 | c.1861G>A p.A621T (on ENST00000621492; = p.A587T on NM_025248.3) | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs760418549; called by muse, mutect2, varscan2
- SRSF1 | c.158del p.G53Dfs*85 | Frame Shift Del (DEL) | VAF 59/336 reads (18%) | catalogued as COSV51964296, COSV51965809; called by mutect2, varscan2
- SSTR4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1213927042, COSV54798322, COSV99658418; called by muse, mutect2
- STARD9 | c.8057C>T p.A2686V | Missense Mutation (SNP) | VAF 61/335 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1354619556; called by muse, mutect2, varscan2
- SYT16 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777540095, COSV70856141; called by muse, mutect2, varscan2
- TADA2B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 64/447 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs771996154, COSV53828195; called by muse, mutect2, varscan2
- TARM1 | c.340del p.H114Tfs*14 (on ENST00000616041 / NM_001330650.1; = p.H106Tfs*14 on NM_001135686.3) | Frame Shift Del (DEL) | VAF 43/338 reads (13%) | catalogued as rs773860043; called by mutect2, varscan2
- TAS2R42 | c.745del p.S249Pfs*18 | Frame Shift Del (DEL) | VAF 32/248 reads (13%) | catalogued as rs753101364; called by mutect2, varscan2
- TBX3 | c.1421C>T p.P474L (on ENST00000257566 / NM_016569.4; = p.P454L on NM_005996.4) | Missense Mutation (SNP) | VAF 29/325 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs762031545; called by muse, mutect2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 52/322 reads (16%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF3 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 31/142 reads (22%) | catalogued as rs746665695, COSV53645113; called by muse, mutect2, varscan2
- TCF7L2 | c.598del p.L200Sfs*25 (on ENST00000355995 / NM_001367943.1; = p.L177Sfs*25 on NM_030756.5) | Frame Shift Del (DEL) | VAF 83/313 reads (27%) | catalogued as rs778855667; called by mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 34/168 reads (20%) | catalogued as rs745872748; called by mutect2, varscan2
- TCOF1 | c.3823C>T p.R1275W (on ENST00000377797 / NM_001135243.1; = p.R1198W on NM_000356.4) | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs768512539, CD125104; called by muse, mutect2, varscan2
- TDRD6 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs1351763540, COSV60177012; called by muse, varscan2
- TEAD2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs556204126, COSV60545238; called by mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 36/196 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TESPA1 | c.426del p.T143Pfs*59 (on ENST00000316577 / NM_001098815.3; = p.T5Pfs*59 on NM_014796.2 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/185 reads (13%) | catalogued as rs1365960762; called by mutect2, varscan2
- THAP5 | c.297del p.K99Nfs*25 (on ENST00000415914 / NM_001130475.3; = p.K57Nfs*25 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 58/245 reads (24%) | catalogued as rs745348876; called by mutect2, varscan2
- TIMP1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as rs1476457782, COSV54483887; called by muse, mutect2, varscan2
- TM6SF1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs202192905, COSV51944502; called by muse, mutect2, varscan2
- TNS1 | c.4750G>A p.G1584S | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs371630425, COSV50745723; called by muse, mutect2, varscan2
- TNS1 | c.4265C>A p.P1422H | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50776480; called by muse, mutect2, varscan2
- TNS3 | c.4159G>T p.D1387Y | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234977; called by muse, mutect2, varscan2
- TPR | c.2052dup p.E685Rfs*6 | Frame Shift Ins (INS) | VAF 39/192 reads (20%) | catalogued as rs1432981657; called by mutect2, varscan2
- TRDV2 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1223618670; called by muse, mutect2, varscan2
- TRHR | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 57/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61233346; called by muse, mutect2, varscan2
- TRIM58 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs954995992, COSV63570116; called by muse, mutect2, varscan2
- TRIM6 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1305196235; called by muse, mutect2, varscan2
- TRIO | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs139892017; called by muse, mutect2, varscan2
- TRIO | c.7978C>T p.R2660W | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs748596743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIP12 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 53/360 reads (15%) | catalogued as COSV99390312; called by muse, mutect2, varscan2
- TRPC6 | c.1128del p.K376Nfs*3 | Frame Shift Del (DEL) | VAF 36/152 reads (24%) | catalogued as COSV60250864; called by mutect2, varscan2
- TRPM2 | c.529del p.A177Pfs*6 | Frame Shift Del (DEL) | VAF 80/332 reads (24%) | catalogued as rs762935066, COSV55967995; called by mutect2, varscan2
- TRPM5 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772292156, COSV50144391; called by muse, mutect2, varscan2
- TRPV2 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 43/395 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1263215594, COSV58427534; called by muse, mutect2, varscan2
- TSPYL5 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1389732110, COSV59072251; called by muse, mutect2
- TTLL7 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775482319, COSV53083252; called by muse, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 38/196 reads (19%) | catalogued as rs760251146; called by mutect2, varscan2
- TYK2 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53385611; called by muse, mutect2, varscan2
- UAP1L1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs530235633; called by muse, mutect2, varscan2
- UBE2O | c.3772del p.L1258Sfs*16 | Frame Shift Del (DEL) | VAF 39/278 reads (14%) | catalogued as COSV60068475; called by mutect2, varscan2
- UBTF | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 65/261 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1309107358, COSV57185187; called by muse, mutect2, varscan2
- UGT1A6 | c.1560del p.R522Efs*22 | Frame Shift Del (DEL) | VAF 41/257 reads (16%) | catalogued as COSV59381895; called by mutect2, varscan2
- URB1 | c.1545G>A p.W515* | Nonsense Mutation (SNP) | VAF 74/312 reads (24%) | catalogued as rs189942230; called by muse, mutect2, varscan2
- USF3 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs965721326; called by muse, mutect2, varscan2
- UTP14C | c.71dup p.N24Kfs*6 | Frame Shift Ins (INS) | VAF 83/302 reads (27%) | catalogued as rs769669893; called by mutect2, varscan2
- VCAN | c.9361G>A p.G3121R | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314929549, COSV54108796, COSV99424537; called by muse, mutect2, varscan2
- VIRMA | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs781536712, COSV52585122; called by muse, mutect2, varscan2
- VPS37D | c.712del p.L238Cfs*2 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs1554609756; called by mutect2, varscan2
- VSX2 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as rs781547325; called by muse, mutect2, varscan2
- WDFY4 | c.9332G>A p.R3111Q | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1403277124, COSV55426562; called by muse, mutect2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 37/141 reads (26%) | catalogued as rs1557951659, COSV63058584; called by mutect2, varscan2
- WFS1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 67/359 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs756667462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBED4 | c.2762T>G p.L921R | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53465625; called by muse, mutect2
- ZBTB2 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1220876263; called by muse, mutect2, varscan2
- ZBTB7A | c.674del p.P225Rfs*99 | Frame Shift Del (DEL) | VAF 30/174 reads (17%) | catalogued as rs1555693029; called by mutect2, varscan2
- ZFHX3 | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51717973, COSV51725973, COSV51733095; called by muse, mutect2, varscan2
- ZFHX4 | c.8707A>G p.S2903G | Missense Mutation (SNP) | VAF 111/466 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50493593; called by muse, mutect2, varscan2
- ZIC4 | c.455A>G p.H152R | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs775920052; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 60/213 reads (28%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 26/224 reads (12%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF454 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as rs774761220; called by muse, mutect2, varscan2
- ZNF467 | c.1758dup p.E587Rfs*134 | Frame Shift Ins (INS) | VAF 44/262 reads (17%) | catalogued as rs1178444108; called by mutect2, varscan2
- ZNF469 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs568820656, COSV71259343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF516 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as rs1198066055; called by muse, mutect2, varscan2
- ZNF536 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.73); catalogued as rs762428720, COSV99052767; called by muse, mutect2, varscan2
- ZNF555 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs764653741, COSV62073279, COSV62073849; called by muse, mutect2, varscan2
- ZNF648 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs770207027, COSV60570619; called by muse, mutect2, varscan2
- ZNF653 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1247589333; called by muse, mutect2, varscan2
- ZNF654 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 21/374 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1364119418; called by muse, mutect2
- ZNF71 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60146866; called by muse, mutect2, varscan2
- ZNF763 | c.842del p.G281Efs*117 (on ENST00000358987 / NM_001367172.2; = p.G284Efs*117 on NM_001012753.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 50/244 reads (20%) | catalogued as COSV59689278; called by mutect2, varscan2
- ZNF90 | c.513del p.K171Nfs*6 | Frame Shift Del (DEL) | VAF 31/194 reads (16%) | catalogued as rs782729171; called by mutect2, varscan2
- A2ML1 | c.2654A>G p.K885R | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ABCC11 | c.630del p.L211Sfs*5 | Frame Shift Del (DEL) | VAF 52/292 reads (18%) | called by mutect2, varscan2
- ABCC2 | c.2822A>G p.E941G | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABHD14B | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABHD8 | c.54del p.N19Tfs*18 | Frame Shift Del (DEL) | VAF 49/227 reads (22%) | called by mutect2, varscan2
- AC092718.8 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2
- AC131160.1 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ACIN1 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTL7B | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ADAD2 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 55/341 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2
- AFDN | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 96/437 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- AGR2 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 77/399 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- AKAP12 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKAP13 | c.3113A>G p.N1038S | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKAP13 | c.8141C>A p.S2714Y (on ENST00000394518 / NM_007200.5; = p.S2718Y on NM_006738.6) | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ALOXE3 | c.296T>C p.F99S | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AMPD1 | c.1549A>G p.M517V | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANGPTL2 | c.654del p.A219Lfs*30 | Frame Shift Del (DEL) | VAF 56/292 reads (19%) | called by mutect2, varscan2
- ANKRD29 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ANO8 | c.3493del p.R1165Afs*154 | Frame Shift Del (DEL) | VAF 17/77 reads (22%) | called by mutect2, varscan2
- ANO9 | c.1433T>C p.M478T | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- AP1G1 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, varscan2
- APC2 | c.6689T>C p.V2230A | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ARHGAP6 | c.2864G>T p.W955L (on ENST00000337414 / NM_013427.3; = p.W752L on NM_013423.3) | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGEF10L | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 56/309 reads (18%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ARHGEF18 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ARHGEF40 | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ARID5B | c.2126C>A p.P709H | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ARRDC1 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARRDC3 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2
- ASB16 | c.1313del p.P438Rfs*53 | Frame Shift Del (DEL) | VAF 46/248 reads (19%) | called by mutect2, varscan2
- ASTE1 | c.694A>G p.M232V | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG9B | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ATOH8 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATP2B4 | c.3569A>G p.Q1190R | Missense Mutation (SNP) | VAF 22/383 reads (6%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); called by muse, mutect2
- ATP4B | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 49/424 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ATP6V1FNB | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- B3GALNT1 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 55/347 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BARX1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.077); called by muse, mutect2
- BAZ1B | c.2086T>G p.L696V | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BBC3 | c.247del p.R83Afs*146 (on ENST00000449228 / NM_001127240.3; = p.A49Pfs*166 on NM_014417.5) | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, varscan2
- BCAR3 | c.2120T>C p.V707A | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, varscan2
- BCL9L | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- BEND4 | c.93dup p.S32Qfs*122 | Frame Shift Ins (INS) | VAF 22/175 reads (13%) | called by mutect2, varscan2
- BICD1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2
- BICDL2 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 35/208 reads (17%) | called by muse, mutect2, varscan2
- BMP4 | c.102del p.V35Sfs*83 | Frame Shift Del (DEL) | VAF 54/261 reads (21%) | called by mutect2, varscan2
- BOC | c.527A>T p.N176I | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- BRINP1 | c.1627G>T p.G543C | Missense Mutation (SNP) | VAF 44/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTG3 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BTK | c.1309A>G p.M437V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 41/184 reads (22%) | called by mutect2, varscan2
- C10orf105 | c.106del p.L36Sfs*21 | Frame Shift Del (DEL) | VAF 58/334 reads (17%) | called by mutect2, varscan2
- C10orf67 | c.23G>A p.R8K (on ENST00000323327; = p.R9K on NM_153714.3) | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C17orf75 | c.464del p.L155* | Frame Shift Del (DEL) | VAF 30/268 reads (11%) | called by mutect2, varscan2
- CACNA1G | c.4181G>A p.R1394Q | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CADPS2 | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- CAMK1D | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMTA2 | c.842dup p.E282Rfs*29 | Frame Shift Ins (INS) | VAF 54/298 reads (18%) | called by mutect2, varscan2
- CARMIL3 | c.4093G>T p.G1365* | Nonsense Mutation (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2, varscan2
- CASKIN1 | c.2332dup p.Q778Pfs*91 | Frame Shift Ins (INS) | VAF 51/243 reads (21%) | called by mutect2, varscan2
- CCDC168 | c.10019C>T p.A3340V | Missense Mutation (SNP) | VAF 80/320 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CCL23 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CD4 | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2
- CDK11B | c.110del p.N37Ifs*17 | Frame Shift Del (DEL) | VAF 34/215 reads (16%) | called by mutect2, varscan2
- CDK14 | c.433T>C p.S145P (on ENST00000380050 / NM_001287135.2; = p.S127P on NM_012395.3) | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CDK16 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- CELSR3 | c.1392del p.N465Tfs*69 | Frame Shift Del (DEL) | VAF 52/214 reads (24%) | called by mutect2, varscan2
- CFAP97D2 | c.303del p.K102Rfs*33 | Frame Shift Del (DEL) | VAF 38/246 reads (15%) | called by mutect2, varscan2
- CHDH | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CHIT1 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.314); called by muse, mutect2
- CHRM1 | c.800G>T p.R267M | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); called by muse, varscan2
- CHRM1 | c.718A>G p.S240G | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, varscan2
- CIZ1 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLCN2 | c.1493del p.G498Afs*14 | Frame Shift Del (DEL) | VAF 36/178 reads (20%) | called by mutect2, varscan2
- CLEC17A | c.38del p.P13Hfs*107 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | called by mutect2, varscan2
- CNTN1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 23/313 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2
- COL5A1 | c.1846G>A p.G616R | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COL5A3 | c.3927del p.G1310Afs*83 | Frame Shift Del (DEL) | VAF 53/300 reads (18%) | called by mutect2, varscan2
- COPE | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- CPEB3 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPNE1 | c.698A>G p.Q233R (on ENST00000352393; = p.Q238R on NM_003915.5) | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPPED1 | c.826del p.H276Tfs*20 | Frame Shift Del (DEL) | VAF 76/392 reads (19%) | called by mutect2, varscan2
- CPSF4 | c.539del p.P180Hfs*24 | Frame Shift Del (DEL) | VAF 47/253 reads (19%) | called by mutect2, varscan2
- CR1L | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CRTC1 | c.535del p.R179Efs*5 | Frame Shift Del (DEL) | VAF 40/228 reads (18%) | called by mutect2, varscan2
- CSPG4 | c.5824A>G p.I1942V | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTSZ | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2
- CUL2 | c.194del p.L65Wfs*54 | Frame Shift Del (DEL) | VAF 48/274 reads (18%) | called by mutect2, varscan2
- CUX1 | c.983A>C p.E328A (on ENST00000292535 / NM_181552.4; = p.E339A on NM_001913.5) | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CYFIP2 | c.3376A>G p.S1126G (on ENST00000616178 / NM_001291722.2; = p.S1101G on NM_014376.4) | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.042); called by muse, mutect2
- CYP2A13 | c.495C>T p.G165= | Splice Region (SNP) | VAF 67/282 reads (24%) | called by muse, mutect2, varscan2
- CYP2C19 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP4F2 | c.703dup p.R235Kfs*4 | Frame Shift Ins (INS) | VAF 51/270 reads (19%) | called by mutect2, varscan2
- DAAM1 | c.3200G>A p.S1067N | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DCTN1 | c.1961C>A p.A654D | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); called by muse, mutect2
- DDX39A | c.496dup p.H166Pfs*17 | Frame Shift Ins (INS) | VAF 50/252 reads (20%) | called by mutect2, varscan2
- DHX38 | c.3047T>C p.L1016P | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DLC1 | c.3302A>C p.Y1101S (on ENST00000276297 / NM_001348081.2; = p.Y664S on NM_006094.5) | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- DLC1 | c.1904A>G p.D635G (on ENST00000276297 / NM_001348081.2; = p.D198G on NM_006094.5) | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.398); called by muse, mutect2
- DLX4 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- DMBT1 | c.7076A>G p.Y2359C (on ENST00000338354 / NM_001377530.1; = p.Y1602C on NM_004406.3) | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- DNAAF2 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNAH6 | c.7613A>G p.Q2538R | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH7 | c.8951C>T p.A2984V | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DOCK10 | c.5342del p.L1781* | Frame Shift Del (DEL) | VAF 49/301 reads (16%) | called by mutect2, varscan2
- DOP1B | c.1865G>A p.S622N | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DSCAML1 | c.2333del p.P778Hfs*36 (on ENST00000321322; = p.P718Hfs*36 on NM_020693.4) | Frame Shift Del (DEL) | VAF 40/240 reads (17%) | called by mutect2, varscan2
- DSG1 | c.1700dup p.L567Ffs*6 | Frame Shift Ins (INS) | VAF 50/235 reads (21%) | called by mutect2, varscan2
- DTX4 | c.1222-1G>A p.X408_splice | Splice Site (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- EIF4E3 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EIF4G2 | c.2171T>C p.L724P | Missense Mutation (SNP) | VAF 75/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELP1 | c.621dup p.A208Cfs*28 | Frame Shift Ins (INS) | VAF 38/237 reads (16%) | called by mutect2, varscan2
- ERBIN | c.2883del p.T962Qfs*39 | Frame Shift Del (DEL) | VAF 49/296 reads (17%) | called by mutect2, varscan2
- ERMARD | c.1801A>G p.N601D | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- ESCO1 | c.55del p.S19Vfs*17 | Frame Shift Del (DEL) | VAF 30/206 reads (15%) | called by mutect2, varscan2
- ETV3 | c.730del p.H244Tfs*26 | Frame Shift Del (DEL) | VAF 62/308 reads (20%) | called by mutect2, varscan2
- EVI2B | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EXPH5 | c.4638G>T p.E1546D | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.067); called by muse, mutect2
- EZH1 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM120B | c.2165G>A p.C722Y | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM135B | c.2978T>G p.V993G | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- FAM186A | c.5219T>C p.L1740P | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- FAT1 | c.377del p.N126Ifs*20 | Frame Shift Del (DEL) | VAF 66/272 reads (24%) | called by mutect2, varscan2
- FAT2 | c.91T>C p.W31R | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- FBN2 | c.1847T>C p.V616A | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FBN3 | c.7820del p.G2607Afs*91 | Frame Shift Del (DEL) | VAF 52/255 reads (20%) | called by mutect2, varscan2
- FBXL13 | c.1676T>C p.L559P | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FBXO31 | c.706C>A p.H236N | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FBXO34 | c.1454del p.L485Cfs*13 | Frame Shift Del (DEL) | VAF 63/359 reads (18%) | called by mutect2, varscan2
- FKBP5 | c.390dup p.E131* | Frame Shift Ins (INS) | VAF 35/168 reads (21%) | called by mutect2, varscan2
- FLG | c.3181A>G p.S1061G | Missense Mutation (SNP) | VAF 65/399 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLG2 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- FMO5 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC3A | c.862C>T p.P288S (on ENST00000492622 / NM_001079673.2; = p.P232S on NM_014923.5) | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.035); called by muse, mutect2
- FOXK2 | c.1316T>G p.V439G | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- FPGS | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- FZD10 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- GPATCH4 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPATCH8 | c.2207dup p.G737Wfs*17 | Frame Shift Ins (INS) | VAF 74/368 reads (20%) | called by mutect2, varscan2
- GPC5 | c.675dup p.L226Sfs*9 | Frame Shift Ins (INS) | VAF 86/310 reads (28%) | called by mutect2, varscan2
- GPD2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GPRASP1 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- GRK3 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRM1 | c.3127A>G p.T1043A | Missense Mutation (SNP) | VAF 59/399 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSG1L2 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2
- H2AC11 | c.111A>C p.K37N | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 38/267 reads (14%) | called by mutect2, varscan2
- HERC2 | c.13439del p.G4480Afs*7 | Frame Shift Del (DEL) | VAF 44/233 reads (19%) | called by mutect2, varscan2
- HNRNPL | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- HSF1 | c.906del p.S303Afs*8 | Frame Shift Del (DEL) | VAF 44/213 reads (21%) | called by mutect2, varscan2
- HSPA12B | c.205A>C p.T69P | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HSPA1L | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 88/480 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPA2 | c.1858_1863del p.G620_G621del | In Frame Del (DEL) | VAF 76/482 reads (16%) | called by mutect2, varscan2
- HTR1E | c.923del p.F308Sfs*5 | Frame Shift Del (DEL) | VAF 34/310 reads (11%) | called by mutect2, varscan2
- IDH3G | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IFNL1 | c.254G>T p.R85M | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- IFT57 | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- ILVBL | c.233T>A p.I78N | Missense Mutation (SNP) | VAF 73/337 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IMPG2 | c.341A>G p.Q114R | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 42/186 reads (23%) | called by mutect2, varscan2
- INSM1 | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INTS1 | c.3692T>C p.L1231P | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- IPO7 | c.489del p.K163Nfs*9 | Frame Shift Del (DEL) | VAF 23/166 reads (14%) | called by mutect2, varscan2
- ITGA2 | c.2072dup p.N691Kfs*9 | Frame Shift Ins (INS) | VAF 46/297 reads (15%) | called by mutect2, varscan2
- ITGA2 | c.2687A>T p.D896V | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ITGAD | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAL | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- JPH4 | c.1090G>T p.V364F | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KALRN | c.8169A>T p.E2723D (on ENST00000360013 / NM_001024660.4; = p.E1026D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.005); called by muse, mutect2
- KCNC3 | c.1060del p.V354Cfs*74 | Frame Shift Del (DEL) | VAF 52/310 reads (17%) | called by mutect2, varscan2
- KCNG3 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDM4C | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5C | c.3842T>G p.L1281R | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1217 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.745); called by muse, mutect2
- KIAA1755 | c.1536A>C p.K512N | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- KLHDC7B | c.1517C>T p.A506V (on ENST00000395676; = p.A1147V on NM_138433.5) | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.057); called by muse, mutect2
- KLHL12 | c.708A>G p.I236M | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2
- KNOP1 | c.1109A>C p.E370A | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); called by muse, mutect2
- KRT83 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- KRTAP19-1 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 40/615 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- L3MBTL1 | c.956A>C p.Q319P (on ENST00000418998 / NM_001377303.1; = p.Q229P on NM_015478.7) | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L3MBTL2 | c.209A>G p.H70R | Missense Mutation (SNP) | VAF 26/375 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2
- LACTB | c.686del p.K229Rfs*2 | Frame Shift Del (DEL) | VAF 25/173 reads (14%) | called by mutect2, varscan2
- LAMA5 | c.10704dup p.Y3569Lfs*17 | Frame Shift Ins (INS) | VAF 56/279 reads (20%) | called by mutect2, varscan2
- LAMB2 | c.1079T>C p.M360T | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- LARGE1 | c.2227G>A p.G743S | Missense Mutation (SNP) | VAF 81/398 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- LCE1E | c.38del p.P13Lfs*65 | Frame Shift Del (DEL) | VAF 88/297 reads (30%) | called by mutect2, varscan2
- LOX | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRBA | c.2550T>A p.F850L | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRP2 | c.6896dup p.I2300Dfs*31 | Frame Shift Ins (INS) | VAF 40/322 reads (12%) | called by mutect2, varscan2
- LRP6 | c.3373C>T p.R1125* | Nonsense Mutation (SNP) | VAF 48/285 reads (17%) | called by muse, mutect2, varscan2
- LRP8 | c.1469T>A p.V490D | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- LRRC43 | c.1688A>G p.Q563R | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC57 | c.713T>C p.F238S | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); called by muse, mutect2
- LRRC8C | c.541dup p.E181Gfs*38 | Frame Shift Ins (INS) | VAF 38/204 reads (19%) | called by mutect2, varscan2
- LRRN1 | c.1979dup p.N660Kfs*20 | Frame Shift Ins (INS) | VAF 53/247 reads (21%) | called by mutect2, varscan2
- LUC7L | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LYN | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- MAGEB6 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MAP3K11 | c.2476del p.Q826Rfs*121 | Frame Shift Del (DEL) | VAF 57/296 reads (19%) | called by mutect2, varscan2
- MAP3K21 | c.2143dup p.Q715Pfs*30 | Frame Shift Ins (INS) | VAF 52/284 reads (18%) | called by mutect2, varscan2
- MAS1L | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 52/761 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2
- MBD1 | c.1354C>T p.P452S (on ENST00000269468 / NM_001323950.1; = p.P396S on NM_002384.2) | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.406); called by muse, mutect2
- MBD2 | c.293del p.P98Rfs*67 | Frame Shift Del (DEL) | VAF 25/141 reads (18%) | called by mutect2, varscan2
- MED15 | c.1850T>C p.L617P (on ENST00000263205 / NM_001003891.3; = p.L577P on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGA | c.9196T>C p.*3066Rext*51 (on ENST00000219905 / NM_001164273.1; = p.*2857Rext*51 on NM_001080541.2) | Nonstop Mutation (SNP) | VAF 39/267 reads (15%) | called by muse, mutect2, varscan2
- MGAM | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MGAM | c.3386A>G p.K1129R | Missense Mutation (SNP) | VAF 40/607 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- MICU2 | c.594del p.F198Lfs*7 | Frame Shift Del (DEL) | VAF 37/212 reads (17%) | called by mutect2, varscan2
- MMP15 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP16 | c.923del p.P308Hfs*43 | Frame Shift Del (DEL) | VAF 118/468 reads (25%) | called by mutect2, varscan2
- MNT | c.237_239del p.L80del | In Frame Del (DEL) | VAF 41/312 reads (13%) | called by mutect2, varscan2
- MON1B | c.1007dup p.Y337Lfs*22 | Frame Shift Ins (INS) | VAF 48/264 reads (18%) | called by mutect2, varscan2
- MON1B | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.034); called by muse, mutect2
- MPP2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MRGPRX2 | c.581del p.L194Yfs*25 | Frame Shift Del (DEL) | VAF 42/374 reads (11%) | called by mutect2, varscan2
- MSR1 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTCL1 | c.1565del p.K522Rfs*5 (on ENST00000306329 / NM_001378206.1; = p.K162Rfs*5 on NM_015210.4) | Frame Shift Del (DEL) | VAF 52/258 reads (20%) | called by mutect2, varscan2
- MYH2 | c.2107G>A p.G703S | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- MYRF | c.2236G>A p.V746M (on ENST00000278836 / NM_001127392.3; = p.V737M on NM_013279.4) | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NAP1L3 | c.1036A>G p.K346E | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NCKAP1 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- NCOR2 | c.5404C>T p.R1802* | Nonsense Mutation (SNP) | VAF 92/430 reads (21%) | called by muse, mutect2, varscan2
- NDUFB2 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEB | c.16423C>A p.L5475I | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NEB | c.2214T>C p.H738= | Splice Region (SNP) | VAF 27/185 reads (15%) | called by muse, mutect2, varscan2
- NEK10 | c.1097T>A p.I366N | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NEMF | c.1336_1337del p.K446Efs*2 | Frame Shift Del (DEL) | VAF 60/290 reads (21%) | called by mutect2, varscan2
- NEURL3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NIT1 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKX1-1 | c.1024A>C p.I342L | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NKX1-1 | c.803del p.G268Afs*73 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | called by mutect2, varscan2
- NLRP8 | c.2192A>G p.Q731R | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- NOL9 | c.1824T>C p.F608= | Splice Region (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- NOTCH1 | c.7270G>A p.A2424T | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- NR2E3 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- NRDE2 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NSRP1 | c.257del p.K86Rfs*23 | Frame Shift Del (DEL) | VAF 29/212 reads (14%) | called by mutect2, varscan2
- NYAP1 | c.991C>A p.L331I | Missense Mutation (SNP) | VAF 65/337 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ODF3B | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ONECUT1 | c.1104A>G p.A368= | Splice Region (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- OPLAH | c.2000T>C p.F667S | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR1M1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- OR2L13 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- OR7E24 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR9A2 | c.81dup p.A28Cfs*25 | Frame Shift Ins (INS) | VAF 39/299 reads (13%) | called by mutect2, varscan2
- OSBP2 | c.1940T>A p.I647N | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- P4HA3 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PALB2 | c.1391G>A p.R464K | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHB15 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 85/505 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDHB7 | c.1617dup p.A540Rfs*188 | Frame Shift Ins (INS) | VAF 84/484 reads (17%) | called by mutect2, varscan2
- PCDHB9 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA3 | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCDHGC5 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCIF1 | c.1667T>C p.F556S | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PCLO | c.7796A>G p.Q2599R | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PERM1 | c.1765T>C p.C589R | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFKFB4 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 63/275 reads (23%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- PGC | c.892del p.A298Pfs*11 | Frame Shift Del (DEL) | VAF 42/217 reads (19%) | called by mutect2, varscan2
- PHACTR4 | c.569C>T p.T190I (on ENST00000373839 / NM_001350159.2; = p.T200I on NM_023923.4) | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHKA2 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PIGB | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PIGO | c.3149T>C p.F1050S | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIH1D2 | c.377del p.N126Ifs*3 | Frame Shift Del (DEL) | VAF 52/216 reads (24%) | called by mutect2, varscan2
- PIR | c.827dup p.N276Kfs*4 | Frame Shift Ins (INS) | VAF 37/138 reads (27%) | called by mutect2, varscan2
- PIWIL3 | c.1848del p.V617Sfs*14 | Frame Shift Del (DEL) | VAF 48/256 reads (19%) | called by mutect2, varscan2
- PKD2L1 | c.362T>C p.M121T | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2
- PLAGL1 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLCB3 | c.2070del p.F690Lfs*43 | Frame Shift Del (DEL) | VAF 26/208 reads (13%) | called by mutect2, varscan2
- PLG | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 72/363 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PNPLA5 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 62/357 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PNPLA8 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.679T>G p.C227G | Missense Mutation (SNP) | VAF 90/452 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLR1A | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPARGC1B | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PRKAG1 | c.974C>T p.T325I | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by mutect2, varscan2
- PRR12 | c.2456del p.N819Ifs*8 (on ENST00000615927; = p.N1640Ifs*8 on NM_020719.3) | Frame Shift Del (DEL) | VAF 32/184 reads (17%) | called by mutect2, varscan2
- PRRC2B | c.3277del p.V1093Sfs*77 | Frame Shift Del (DEL) | VAF 43/269 reads (16%) | called by mutect2, varscan2
- PRRC2B | c.5926A>G p.R1976G | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRRT3 | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2
- PRSS55 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMD5 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PTPN12 | c.2135del p.K712Sfs*5 | Frame Shift Del (DEL) | VAF 43/253 reads (17%) | called by mutect2, varscan2
- PTPRQ | c.1060T>C p.C354R (on ENST00000616559; = p.C312R on NM_001145026.2) | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- RAB3A | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 30/401 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB3GAP2 | c.3563del p.N1188Mfs*7 | Frame Shift Del (DEL) | VAF 34/148 reads (23%) | called by mutect2, varscan2
- RAB3IL1 | c.955del p.D319Tfs*46 | Frame Shift Del (DEL) | VAF 69/283 reads (24%) | called by mutect2, varscan2
- RALY | c.436A>G p.K146E (on ENST00000246194 / NM_016732.3; = p.K130E on NM_007367.4) | Missense Mutation (SNP) | VAF 34/401 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- RANBP3L | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- RBM17 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RGS9 | c.395del p.K132Rfs*16 | Frame Shift Del (DEL) | VAF 54/277 reads (19%) | called by mutect2, varscan2
- RHBDF2 | c.1406T>C p.L469P | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RIF1 | c.4514del p.K1505Rfs*18 | Frame Shift Del (DEL) | VAF 33/278 reads (12%) | called by mutect2, varscan2
- RNF103 | c.807A>C p.E269D | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RNF103 | c.609del p.F203Lfs*4 | Frame Shift Del (DEL) | VAF 56/298 reads (19%) | called by mutect2, varscan2
- RNF148 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RPTOR | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RSPH6A | c.884A>T p.E295V | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTEL1 | c.1775C>A p.P592H | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RUNDC1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- S100A2 | c.262A>G p.N88D | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SBNO2 | c.695del p.P232Qfs*21 | Frame Shift Del (DEL) | VAF 62/354 reads (18%) | called by mutect2, varscan2
- SCARA5 | c.1063del p.A355Pfs*37 | Frame Shift Del (DEL) | VAF 78/234 reads (33%) | called by mutect2, varscan2
- SCYL1 | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 21/329 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- SDF4 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2
- SDSL | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SEL1L3 | c.391del p.R131Gfs*15 | Frame Shift Del (DEL) | VAF 36/229 reads (16%) | called by mutect2, varscan2
- SEMA6C | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERINC4 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 74/462 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SERTAD1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SF3A2 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SFN | c.539A>G p.H180R | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- SH3RF3 | c.1396del p.L466Sfs*42 | Frame Shift Del (DEL) | VAF 60/258 reads (23%) | called by mutect2, varscan2
- SIN3A | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIPA1L2 | c.2535G>T p.K845N | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIX3 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SIX6 | c.7del p.Q3Sfs*5 | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | called by mutect2, varscan2
- SLC15A1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC18A3 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC22A1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.035); called by muse, mutect2
397 further variants in this file (93 protein-altering or splice-affecting, 256 silent, 48 other) are not listed here.
